Surgical pathology report (de-identified scan), TCGA case TCGA-E7-A97Q, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Asterand, specimen TCGA-E7-A97Q-01A (Primary Tumor).

[page 1 of 2]
TSS Patient ID:

Surgical Date:

Gross Description: Soft, lobular, yellow-red adipose

Peritoneal reflection of posterior aspect contains a

5.5 x 3 cm indurated,

puckered area on the left side, which is inked green

8.5 x 4 (RL) cm included anterior vaginal wall with smooth, pink-tan

mucosa extending to the distal urethral margin. Right is inked black, left

inked blue.

ICD-O-3

Carcinoma, urothelial
(transitional cell) 8120/3
Site: 4 Bladder NOS C67.9
q2 417/14

Microscopic Description: Microscopic Description

Invasive urothelial carcinoma, high grade, moderately to poorly

differentiated

- Carcinoma invades through muscularis propria into perivesicular adipose

tissue and extends into the stroma of the vaginal wall and into the

exterior wall of the left ureter

- Size: 6.5 cm in greatest dimension

- Angiolymphatic and perineural invasion present

Diagnosis Details: Diagnostic Details

Urothelial (transitional cell) Carcinoma

High Grade

Invades perivesical tissue and adjacent structures (vagina, external wall of left ureter)

Angiolymphatic invasion present

pT4a pN3

Comments: Immunohistochemical stain p16 is moderate to strong and diffusely

[page 2 of 2]
positive within the vaginal dysplasia consistent with the diagnosis of high-grade squamous dysplasia (slide H7). The urothelial carcinoma is widely invasive and extends into the vaginal wall

Formatted Path Reports: BLADDER TISSUE CHECKLIST

Specimen type: Excision of tumor

Tumor site: Bladder

Tumor size: 6.5 x 5 x 1.5 cm

Tumor features: None specified

Histologic type: Transitional cell carcinoma

Histologic grade: Poorly to moderately differentiated

Tumor extent: Perivesical tissue (macroscopic)

Lymph nodes: 20/48 positive for metastasis (Regional 20/48)

Lymphatic invasion: Present

Venous invasion: Present

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

Source: NCI Genomic Data Commons file 1d421cd7-3eed-4a5e-a44c-8062796a61d2 (TCGA-E7-A97Q.E7CE7632-FA80-4509-AC4D-C0EC646E6CB7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).